Somatic mutation profile of tumor specimen TCGA-NC-A5HL-01A (aliquot TCGA-NC-A5HL-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.9 years (26,977 days).
Specimen TCGA-NC-A5HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cb0c7e4-65e4-498e-9643-6d97c5378f90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HL-10A (Blood Derived Normal), aliquot TCGA-NC-A5HL-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a291df0-2dc5-4cd7-91c2-d1ba4cc5ff77

The open-access MAF lists 229 somatic variants for this specimen: 162 protein-altering or splice-affecting, 58 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 58, Nonsense Mutation 6, Intron 3, Frame Shift Del 3, Splice Site 2, 3'UTR 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100205573; called by muse, mutect2, varscan2
- ACVR2B | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100754149; called by muse, mutect2, varscan2
- ACVR2B | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754150; called by muse, mutect2, varscan2
- ADAMTS12 | c.4006A>G p.R1336G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100710221; called by muse, mutect2, varscan2
- AGT | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100794192; called by muse, varscan2
- ANK3 | c.5974T>C p.F1992L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.182); catalogued as COSV99778122; called by muse, mutect2, varscan2
- ANKRD50 | c.2934A>C p.E978D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101538878; called by muse, mutect2, varscan2
- AP4E1 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99956232; called by muse, mutect2, varscan2
- ARHGAP15 | c.1271T>A p.L424H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV99708160; called by muse, mutect2, varscan2
- ARHGDIA | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV99482461; called by muse, mutect2, varscan2
- ASCC3 | c.2642C>T p.T881I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100225153; called by muse, mutect2
- ATP6V1C2 | c.998G>A p.S333N (on ENST00000272238 / NM_001039362.2; = p.S287N on NM_144583.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs753128068, COSV99694369; called by muse, mutect2, varscan2
- B3GAT2 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100016591; called by muse, mutect2, varscan2
- B3GNT8 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1451415778, COSV99524395; called by muse, mutect2, varscan2
- BAG4 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs867892951, COSV99781692; called by muse, mutect2, varscan2
- BPIFA3 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV100966988; called by muse, mutect2, varscan2
- BRWD3 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100955619; called by muse, mutect2, varscan2
- BZW1 | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV100729819; called by muse, mutect2
- C1GALT1 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99777490; called by muse, mutect2, varscan2
- CACNA1A | c.2818C>A p.Q940K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV100800684; called by muse, mutect2, varscan2
- CALN1 | c.395C>T p.T132I (on ENST00000329008 / NM_001017440.3; = p.T174I on NM_031468.4) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100204188; called by muse, mutect2, varscan2
- CCDC197 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100113590, COSV100113597; called by muse, mutect2, varscan2
- CD163L1 | c.2801C>A p.A934D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549618, COSV58025076; called by muse, mutect2
- CELSR2 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 43/240 reads (18%) | catalogued as COSV54781686; called by muse, mutect2, varscan2
- CENPM | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs528182327, COSV53244973, COSV99317766; called by muse, mutect2, varscan2
- CFAP157 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as COSV100076680; called by muse, mutect2, varscan2
- CLEC4F | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1189800903, COSV99713507; called by muse, mutect2, varscan2
- CLSTN3 | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as rs371509493; called by muse, mutect2, varscan2
- CNGA3 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV99735990; called by muse, mutect2, varscan2
- CRBN | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99214031; called by muse, mutect2, varscan2
- CSF3R | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100117257, COSV58973464; called by muse, mutect2, varscan2
- CWC22 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99843927; called by muse, mutect2, varscan2
- CYP2B6 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 38/838 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100137273; called by muse, mutect2
- DENND1C | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV101200138; called by muse, mutect2, varscan2
- DMBT1 | c.3566T>G p.V1189G (on ENST00000338354 / NM_001377530.1; = p.V690G on NM_004406.3) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100351959, COSV100352347; called by muse, mutect2, varscan2
- DOCK6 | c.3284G>T p.S1095I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV99624588; called by muse, mutect2
- DPP10 | c.1859G>T p.G620V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414050627, COSV100058089; called by muse, mutect2, varscan2
- DSEL | c.1604G>A p.W535* | Nonsense Mutation (SNP) | VAF 47/75 reads (63%) | catalogued as COSV100025215; called by muse, mutect2, varscan2
- EML1 | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV99214465; called by muse, mutect2, varscan2
- EPB41L3 | c.2141C>A p.A714E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV100548090; called by muse, mutect2, varscan2
- ERICH3 | c.4208T>A p.V1403E | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100443304; called by muse, mutect2, varscan2
- FAM120A | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV99464401; called by muse, mutect2, varscan2
- FAM135B | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs773045954, COSV52714868, COSV99418374; called by muse, mutect2, varscan2
- FAM227B | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs1039076258, COSV100174390; called by muse, mutect2, varscan2
- FAM237A | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); catalogued as COSV101405565; called by muse, mutect2
- FAT3 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961466; called by muse, mutect2
- FAT4 | c.7198A>T p.S2400C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100627169; called by muse, mutect2, varscan2
- FCRL3 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100942781, COSV63841835; called by muse, mutect2, varscan2
- FMN2 | c.4644+2T>A p.X1548_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100142396; called by muse, mutect2
- FZD8 | c.1229G>T p.S410I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101020178; called by muse, mutect2, varscan2
- GPR84 | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99909927; called by muse, mutect2, varscan2
- GRIA1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752447548, COSV53605030; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM8 | c.2315G>A p.G772D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV100280471; called by muse, mutect2, varscan2
- GUCY1A2 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56495280; called by muse, mutect2, varscan2
- H2BW1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV99474930; called by muse, mutect2, varscan2
- H3-3A | c.300T>A p.Y100* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100831219; called by muse, mutect2, varscan2
- HCN4 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56087161, COSV99983226; called by muse, mutect2, varscan2
- HDHD3 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769600567, COSV99444761; called by muse, mutect2, varscan2
- HFM1 | c.773T>C p.L258S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs753477544, COSV99645273; called by muse, mutect2, varscan2
- HMCN1 | c.9985G>A p.D3329N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV99623671; called by muse, mutect2, varscan2
- HYDIN | c.8150C>T p.S2717F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV59273562; called by muse, mutect2, varscan2
- IFIT5 | c.256T>G p.S86A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100877906; called by muse, mutect2, varscan2
- IFNL3 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as COSV101308010; called by muse, mutect2
- INSL4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.043); catalogued as rs575960188, COSV53329072, COSV53329665; called by muse, mutect2, varscan2
- INTS4 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.197); catalogued as COSV100489844; called by muse, mutect2, varscan2
- ITGAD | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66757017; called by mutect2, varscan2
- KAT6B | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1362389122, COSV99767280; called by muse, mutect2, varscan2
- KLRC2 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV101122627; called by muse, mutect2
- LAS1L | c.804A>T p.R268S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV100408464; called by muse, mutect2, varscan2
- LIPJ | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100905864; called by muse, mutect2, varscan2
- LMOD2 | c.763A>G p.S255G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1187986950, COSV101505405; called by muse, mutect2, varscan2
- LRCH2 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.827); catalogued as COSV100406192; called by muse, mutect2
- LRRC25 | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100170424; called by muse, mutect2
- LRRC37B | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV100495990; called by muse, mutect2, varscan2
- LRRC7 | c.1534G>T p.G512W (on ENST00000651989 / NM_001370785.2; = p.G479W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224260; called by muse, mutect2, varscan2
- LRRC7 | c.1888C>A p.H630N (on ENST00000651989 / NM_001370785.2; = p.H597N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99224264; called by muse, mutect2, varscan2
- MAGEL2 | c.3064G>T p.E1022* | Nonsense Mutation (SNP) | VAF 33/52 reads (63%) | catalogued as COSV100045675, COSV100045705; called by muse, mutect2, varscan2
- MAP2K1 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100198549; called by muse, mutect2, varscan2
- MAP3K21 | c.3071G>C p.R1024P | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100786069; called by muse, mutect2, varscan2
- MAP4K1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99942875; called by muse, mutect2
- METTL18 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99609352; called by muse, mutect2, varscan2
- MLEC | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949561; called by muse, mutect2, varscan2
- MMP16 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV54161178, COSV99685811; called by muse, mutect2, varscan2
- MMP20 | c.477A>T p.R159S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV99497362; called by muse, mutect2, varscan2
- MORC1 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV99224965, COSV99226837; called by muse, mutect2, varscan2
- MPRIP | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs774964369, COSV100505241; called by muse, mutect2, varscan2
- MRPS36 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99840936; called by muse, mutect2, varscan2
- MYO3B | c.1040A>C p.D347A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100509068; called by muse, mutect2, varscan2
- MYO6 | c.3626G>C p.G1209A (on ENST00000369981; = p.G1199A on NM_004999.4) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889250; called by muse, mutect2, varscan2
- NEBL | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV65806337; called by muse, mutect2
- NMNAT3 | c.532G>A p.E178K (on ENST00000296202 / NM_001320512.1; = p.E141K on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV99951368; called by muse, mutect2
- NRSN1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV65893704, COSV65893793; called by muse, mutect2, varscan2
- OPN1SW | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99975426; called by muse, mutect2, varscan2
- OR2L2 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1369382992, COSV100823070, COSV100824038; called by muse, mutect2, varscan2
- OR51T1 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV100434274; called by muse, mutect2, varscan2
- OR5D14 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100162088; called by muse, mutect2, varscan2
- ORC3 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100005577; called by muse, mutect2, varscan2
- OTOF | c.2590C>T p.R864C (on ENST00000272371 / NM_194248.3; = p.R117C on NM_004802.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs150070091; ClinVar: uncertain significance; called by muse, mutect2
- PALM2AKAP2 | c.799G>A p.E267K (on ENST00000259318 / NM_001136562.3; = p.E498K on NM_007203.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99394656; called by muse, mutect2, varscan2
- PAPPA2 | c.4271A>T p.Q1424L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100867499; called by muse, mutect2, varscan2
- PCDHB4 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV99521821; called by muse, mutect2, varscan2
- PCDHB6 | c.1478A>G p.D493G | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99169900; called by muse, varscan2
- PI15 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV99477768; called by muse, mutect2, varscan2
- PIK3CA | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV55911373; called by muse, mutect2
- PLCB1 | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100569232; called by muse, mutect2, varscan2
- PLEC | c.6067C>A p.Q2023K (on ENST00000322810 / NM_201380.4; = p.Q1913K on NM_000445.5) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100510221; called by muse, mutect2, varscan2
- PPP2R3A | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV99386377; called by muse, mutect2, varscan2
- PRDM4 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV99946329; called by muse, mutect2
- PREX2 | c.4759C>G p.P1587A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99904722; called by muse, mutect2
- PRPF40A | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.584); catalogued as COSV100582594; called by muse, mutect2, varscan2
- PTH | c.264T>A p.N88K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV99961662; called by muse, mutect2, varscan2
- RANBP17 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV101206039; called by muse, mutect2, varscan2
- RFX4 | c.1708C>A p.Q570K (on ENST00000392842 / NM_213594.3; = p.Q476K on NM_032491.6) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99985318; called by muse, mutect2, varscan2
- RHBDF1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV51955727; called by muse, mutect2, varscan2
- RNF152 | c.104G>C p.C35S | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100454972; called by muse, mutect2, varscan2
- ROBO4 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100127262; called by muse, mutect2, varscan2
- RPS6KC1 | c.3183G>T p.W1061C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873752; called by muse, mutect2, varscan2
- RSRC2 | c.651A>T p.L217F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV100063292; called by muse, mutect2, varscan2
- RYR1 | c.5954G>T p.S1985I | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1441012614, COSV100614306, COSV62098536; called by muse, mutect2
- RYR2 | c.7661G>T p.R2554I | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100767573, COSV63694678; called by muse, mutect2, varscan2
- SETD6 | c.1349G>C p.R450T (on ENST00000219315 / NM_001160305.4; = p.R426T on NM_024860.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99542984, COSV99543058; called by muse, mutect2, varscan2
- SHOX2 | c.349T>C p.S117P (on ENST00000441443 / NM_006884.3; = p.S141P on NM_003030.4) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.91); catalogued as COSV101273735; called by muse, mutect2
- SI | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.347); catalogued as rs746883962, COSV100013791; called by muse, mutect2, varscan2
- SLC39A12 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV101069822; called by muse, mutect2, varscan2
- SLCO6A1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV101133874; called by muse, mutect2, varscan2
- SMARCA5 | c.2520+1G>T p.X840_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99303411; called by muse, mutect2
- SORBS1 | c.3483T>A p.S1161R | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV99527352; called by muse, mutect2, varscan2
- SPOCK3 | c.674G>T p.S225I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100691717; called by muse, mutect2, varscan2
- SPSB4 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100141000; called by muse, mutect2
- STAT4 | c.142A>T p.N48Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV100635938; called by muse, mutect2, varscan2
- SYT10 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs1447277671, COSV57339686; called by muse, mutect2, varscan2
- TBX4 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV99539846; called by muse, mutect2
- TEK | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.981); catalogued as rs1272264375, COSV101193108, COSV101193512; called by muse, mutect2
- TEK | c.2758C>A p.L920M | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101193109; called by muse, mutect2, varscan2
- TFAP2B | c.703G>C p.G235R | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99539612; called by muse, mutect2
- THOC2 | c.4322A>G p.N1441S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV55555351; called by muse, mutect2, varscan2
- TLR3 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99710803; called by muse, mutect2, varscan2
- TMEM131 | c.3787C>T p.L1263F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as rs1320578372, COSV99486434; called by muse, mutect2, varscan2
- TMPRSS15 | c.2058C>A p.N686K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); catalogued as COSV99516740; called by muse, mutect2, varscan2
- TNS2 | c.2141G>T p.G714V (on ENST00000314250 / NM_170754.4; = p.G724V on NM_015319.2) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1287875165, COSV100036552; called by muse, mutect2, varscan2
- TP53 | c.224del p.P75Lfs*48 | Frame Shift Del (DEL) | VAF 65/162 reads (40%) | catalogued as COSV53349944; called by mutect2, pindel, varscan2
- TTN | c.58787C>A p.T19596N (on ENST00000591111; = p.T12172N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | PolyPhen possibly damaging (0.884); catalogued as COSV100592818; called by muse, mutect2, varscan2
- TXK | c.378G>A p.L126= | Splice Region (SNP) | VAF 64/192 reads (33%) | catalogued as COSV51917406, COSV99972139; called by muse, mutect2, varscan2
- UBAP2 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs369742646; called by muse, mutect2, varscan2
- UCN3 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100991671; called by muse, mutect2, varscan2
- UGT1A6 | c.1523G>C p.C508S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV100529426; called by muse, mutect2, varscan2
- USP13 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV99830681; called by muse, mutect2, varscan2
- VCL | c.2978G>A p.R993H (on ENST00000211998 / NM_014000.3; = p.R925H on NM_003373.4) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53008230; called by muse, mutect2, varscan2
- WIF1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99682539; called by muse, mutect2, varscan2
- YEATS2 | c.3323A>G p.K1108R | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100527431; called by muse, mutect2, varscan2
- ZNF420 | c.1912A>T p.T638S | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100421126; called by muse, mutect2
- ZNF486 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100631053; called by muse, mutect2, varscan2
- ZNF556 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs371475577, COSV56912116; called by muse, mutect2, varscan2
- ZNF708 | c.1484A>C p.K495T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100803031; called by muse, mutect2, varscan2
- ZNF804B | c.3227C>A p.A1076D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100301594; called by muse, mutect2, varscan2
- GGNBP2 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LPIN2 | c.1442del p.G481Efs*25 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- NOP58 | c.1083G>T p.M361I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2
- NRDC | c.1185_1186dup p.M396Kfs*40 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- PGA5 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SLC29A3 | c.158_166del p.T53_I55del | In Frame Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- TAF5 | c.1346_1347del p.K449Tfs*31 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14028C>T p.H4676= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV101291176; called by muse, mutect2, varscan2
- ABCC8 | c.2088G>A p.L696= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100216546; called by muse, mutect2
- ACTN2 | c.2346G>C p.L782= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100856510; called by muse, mutect2, varscan2
- ACTN2 | c.2643C>T p.Y881= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs727505177, COSV63973673; ClinVar: likely benign; called by mutect2, varscan2
- ADIPOR1 | c.1093C>T p.L365= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV100579372; called by muse, mutect2, varscan2
- ATP13A1 | c.1941C>G p.L647= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV52285604; called by muse, mutect2, varscan2
- BTBD10 | c.468A>C p.A156= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV99533313; called by muse, mutect2, varscan2
- CAPN11 | c.1776G>A p.Q592= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV101291838; called by muse, mutect2, varscan2
- CD86 | c.282C>A p.T94= (on ENST00000330540 / NM_175862.5; = p.T88= on NM_006889.4) | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100053818; called by muse, mutect2, varscan2
- CHRM2 | c.969A>T p.T323= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV100280663; called by muse, mutect2, varscan2
- CLOCK | c.492A>G p.S164= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100011548; called by muse, mutect2, varscan2
- CRP | c.189G>T p.S63= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV99660421, COSV99660719; called by muse, mutect2, varscan2
- CYB5R2 | c.417G>C p.T139= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as rs188062300, COSV100207619, COSV55087213; called by muse, mutect2, varscan2
- DCLK1 | c.660C>T p.I220= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99708951; called by muse, mutect2, varscan2
- DIO2 | c.342T>C p.L114= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101375812; called by muse, mutect2
- DOCK4 | c.5649C>G p.P1883= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV101447764, COSV70241193; called by muse, mutect2, varscan2
- ERICH1 | c.819C>T p.D273= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs760467510, COSV50641048; called by muse, mutect2, varscan2
- ETV6 | c.927G>T p.R309= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as COSV101122357; called by muse, mutect2, varscan2
- FAIM2 | c.864G>A p.E288= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100277379; called by muse, mutect2
- FBXL4 | c.1554G>T p.L518= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100013829, COSV100013879; called by muse, mutect2, varscan2
- FCGBP | c.7983C>T p.F2661= | Silent (SNP) | VAF 20/564 reads (4%) | catalogued as COSV99660701; called by muse, mutect2
- FERMT3 | c.1761C>T p.D587= (on ENST00000279227 / NM_178443.3; = p.D583= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs112045200, COSV54172078; called by muse, mutect2, varscan2
- FIGN | c.723C>T p.N241= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100291426; called by muse, varscan2
- FPR1 | c.426C>A p.A142= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV100493910; called by muse, mutect2, varscan2
- GMEB2 | c.414C>T p.T138= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99823407; called by muse, mutect2, varscan2
- GPR88 | c.129C>T p.I43= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100159407, COSV100159412; called by muse, mutect2, varscan2
- HELLS | c.138G>A p.R46= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV99491694; called by muse, mutect2
- HOXD3 | c.261T>C p.N87= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99979865; called by muse, mutect2, varscan2
- HSD3B2 | c.321G>C p.L107= | Silent (SNP) | VAF 86/229 reads (38%) | catalogued as COSV101027408; called by muse, mutect2, varscan2
- ICAM3 | c.981T>C p.H327= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99348856; called by muse, varscan2
- IRX1 | c.444G>A p.E148= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs370898776; called by muse, mutect2, varscan2
- KLF17 | c.618C>T p.P206= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs749586233, COSV100954791; called by muse, mutect2, varscan2
- KLHL4 | c.975T>C p.A325= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs150023774, COSV100909071, COSV64147933; called by muse, mutect2
- LRRC7 | c.1533T>C p.A511= (on ENST00000651989 / NM_001370785.2; = p.A478= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99224258; called by muse, mutect2, varscan2
- LRRIQ1 | c.984A>T p.I328= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV101279420; called by muse, mutect2
- NXPE4 | c.1518C>A p.L506= (on ENST00000375478 / NM_001077639.2; = p.L222= on NM_017678.3) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100970296; called by muse, mutect2, varscan2
- ONECUT2 | c.450G>A p.T150= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1293186761, COSV101529733; called by muse, mutect2, varscan2
- OR1G1 | c.132C>T p.L44= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as rs752208029, COSV100187488, COSV100187591; called by muse, mutect2, varscan2
- OR51T1 | c.87C>T p.I29= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs140019331; called by muse, mutect2, varscan2
- OR52J3 | c.201T>C p.I67= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1320587203, COSV100984780; called by muse, mutect2
- PXDN | c.1386C>A p.P462= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs531175244, COSV99412160; called by muse, varscan2
- RFX4 | c.1707C>A p.S569= (on ENST00000392842 / NM_213594.3; = p.S475= on NM_032491.6) | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV57575918, COSV99985314; called by muse, mutect2, varscan2
- RP1 | c.6237A>T p.S2079= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99606158; called by muse, mutect2, varscan2
- SFTPB | c.528C>A p.L176= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100667098; called by muse, mutect2, varscan2
- SIN3B | c.2892G>A p.V964= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99931349; called by muse, mutect2, varscan2
- SLC17A4 | c.339C>A p.I113= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV100930485; called by muse, varscan2
- SLC25A23 | c.348G>A p.E116= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99901845; called by muse, mutect2, varscan2
- SMARCAL1 | c.582A>T p.T194= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100619727; called by muse, mutect2, varscan2
- SSTR2 | c.552G>A p.R184= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100191950; called by muse, mutect2, varscan2
- STMN2 | c.411G>A p.L137= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99626079; called by muse, mutect2, varscan2
- TEPSIN | c.1002G>T p.P334= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100329507; called by mutect2, varscan2
- TMEM161B | c.159G>C p.G53= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99680169; called by muse, mutect2, varscan2
- TOM1L1 | c.882G>A p.L294= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs878971668, COSV100779127; called by muse, mutect2, varscan2
- TRIM17 | c.1266G>A p.L422= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV52856975; called by muse, mutect2
- VPS72 | c.987C>T p.A329= | Silent (SNP) | VAF 63/137 reads (46%) | called by muse, mutect2, varscan2
- XAGE5 | c.210G>T p.L70= | Silent (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- XIRP2 | c.18G>A p.K6= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1368711952, COSV99738026; called by muse, mutect2, varscan2
- ZNF492 | c.1128G>T p.R376= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101513930; called by mutect2, varscan2
- AP000769.3 | chr11:65502412 ins TG | 5'Flank (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- ERCC6 | c.1397+8470C>T | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as rs745313254, COSV100875645; called by muse, mutect2, varscan2
- MFSD4B | c.*68C>T | 3'UTR (SNP) | VAF 3/37 reads (8%) | catalogued as COSV64349428; called by muse, mutect2
- SPOPL | c.-1G>T | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99699294; called by muse, mutect2, varscan2
- SUGP1 | c.539-185A>G | Intron (SNP) | VAF 154/357 reads (43%) | catalogued as COSV99894481; called by muse, mutect2, varscan2
- SYTL5 | c.*1A>G | 3'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99936861; called by muse, mutect2, varscan2
- TTN | c.34264+5537A>G | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100592822; called by muse, mutect2, varscan2
- UBTFL2 | n.783G>T | RNA (SNP) | VAF 11/54 reads (20%) | called by mutect2, varscan2
- ZNF271P | n.1200G>C | RNA (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
